Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3NP, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3NP-01A (Primary Tumor).

[page 1 of 4]
Surg Path Final Report

* Final Report *

1CD-0-3

* Final Report *

carcinoma, papillary, follicular
variant 8340/3

Site: thyroid, nos C73.9

1/7/12
w

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession: ~~XXXXXXXXXX~~
Physician:

PROCEDURE

Thyroidectomy.

SPECIMEN:

- A. Right thyroid lobe. Frozen.
- B. Parathyroid.
- C. Left subtotal thyroid lobe. Fresh spec.

Reviewed Initials	km	

HISTORY

Vocal cord paralysis. Thyroid mass.

GROSS

A. Received fresh for frozen section diagnosis in a container labeled "right thyroid lobe" is a lobe of thyroid (4.5 x 3 x 2.3 cm, 13 grams). The gland is largely replaced by a 3 cm in greatest dimension discrete nodule with a tan and brown cut surface. The discrete, focally thickened tumor margin is gritty suggestive of calcifications. Smears are prepared from the cut surface. Uninvolved thyroid parenchyma has a uniform red-brown cut surface. A representative portion of the tumor is submitted for the project. The margins are marked with black ink.

Frozen section control. 1NS
1-10. Additional material-nodule.
11-12. Uninvolved thyroid parenchyma.

B. Received fresh for frozen section diagnosis in a container labeled "? parathyroid" is a tan-red tissue fragment (5 mm in greatest dimension, 0.025 grams).

Frozen section control.

C. Received fresh in a container labeled "left thyroid lobe" is a portion of rough-surfaced tan thyroid tissue (3 x 1.6 x 1.2 cm, 2.9 grams). The firm, red-brown parenchyma has a 0.7 cm in diameter, discrete tan nodule with focal calcifications. The margins are marked with black ink. The tissue is submitted in its entirety in three cassettes.

FROZEN SECTION DIAGNOSIS

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 4]
Surg Path Final Report

* Final Report *

- A. Right thyroid nodule:
Follicular lesion suspicious for papillary carcinoma, defer
to permanent sections.
- B. Parathyroid:
Thyroid. No parathyroid seen.

MICROSCOPIC
Performed.

DIAGNOSIS

- A. Right thyroid lobe:
Atypical follicular lesion with focal nuclear features
suspicious for follicular variant of papillary carcinoma, see
note.
- B. Parathyroid:
Thyroid nodule, no parathyroid identified.
- C. Left subtotal thyroid lobe:
Thyroid with benign multinodular hyperplasia.

NOTE: This is a preliminary report. The case is being sent to
for consultation and an addendum report will
follow.

Dr. and Dr. have reviewed this case (Part A).

CPT 88307, 88331 A, 88305, 88331 B,
88307 C

, M.D. (Electronic Signature)

Completed Action List:

* Order by MD, on

Type: Surg Path Final Report
Date:
Status: Auth (Verified)
Title: SURG PATH FINAL REPORT
Encounter info:

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 4]
1st Addendum Report

* Final Report *

* Final Report *

SP 1ST ADDENDUM REPORT

SURGICAL PATHOLOGY

Collected:

Accession:

Physician:

ADDENDUM REPORT

Diagnosis from
M.D., Ph.D.

by Dr.

DIAGNOSIS:

Thyroid, right lobe, excision:

Papillary thyroid carcinoma, well differentiated follicular variant, at least 2 cm, confined to the thyroid. Margins negative.

.....
Dear Dr.

As we discussed today, I have reviewed the slides of the thyroid specimen of your patient, . I completely agree with your opinion that the right lobe contains a follicular variant of papillary carcinoma. Interestingly, the carcinoma appears to be arising in a benign hyperplastic nodule. This makes measuring the carcinoma difficult, but I think it is at least 2 cm in greatest diameter. I do not see extrathyroidal extension and the margins appear close, but negative.

Thank you for allowing me to share in the care of this patient.

M.D. (Electronic Signature)

Completed Action List:

* Order by MD, on

Type: 1st Addendum Report

Printed by:
Printed on:

Page 1 of 2
(Continued)

[page 4 of 4]
1st Addendum Report

* Final Report *

Date:

Status:

Title:

Encounter Info:

Auth (Verified)

SP 1ST ADDENDUM REPORT

[REDACTED]

Printed by:

Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 9d591aba-056c-4bf1-98a8-a37f6173a957 (TCGA-FY-A3NP.F84A8B24-1877-4833-83B5-C417D32D3DB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).